Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EY, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EY-01A (Primary Tumor).

ICD O-3

Melanoma, spindle cell NOS

C69.3

877213

Site Choroid C69.3

C69.4

Capitall C69.4

2/16/14

Enucleation of the right eye.

Macroscopy:

The eyeball measures 30 mm in diameter and the posterior optic nerve segment 11 mm. At the section, it presents a blackish tumor measuring 10 mm main line.

Microscopy

The histological examination reveals a cell proliferation with the histological features of a melanoma. This tumor is composed of fusiform cells with ovoid nucleus harboring frequently nucleolus. Presence of sparse mitotic features (two mitoses per 10 high power field). No necrosis or microcalcifications.

The tumor invades focally the inner part of the sclera, without extrascleral extension. The anterior chamber and the optic nerve on its entire course are free of tumor.

Conclusion:

Uveal melanoma composed of fusiform cells.

Tumor size: 10 mm.

Tumor infiltration of the inner part of the sclera without extrascleral extension.

Optic nerve in its entire course free of tumor.

ICD-9 Discrepancy		✓

Source: NCI Genomic Data Commons file 1c6bfc14-3a69-4871-9e0c-9f5b7ad93d9d (TCGA-V4-A9EY.9C41C5B6-1CDA-4857-B9EC-FE888545783F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).